Somatic mutation profile of tumor specimen ALCH-B2CM-TTP1-A (aliquot ALCH-B2CM-TTP1-A-1-0-D-A776-36) from ALCHEMIST case ALCH-B2CM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 57.4 years (20,966 days).
Specimen ALCH-B2CM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 759a380f-ff01-4589-bc83-64c125bc6c23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2CM-NB1-A (Blood Derived Normal), aliquot ALCH-B2CM-NB1-A-1-0-D-A776-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd08557f-ab02-42d7-8272-524e18560655

The open-access MAF lists 124 somatic variants for this specimen: 89 protein-altering or splice-affecting, 24 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 24, Nonsense Mutation 8, Frame Shift Del 5, Intron 5, RNA 4, Splice Site 3, 5'UTR 1, 3'UTR 1, Translation Start Site 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-1G>C p.X51_splice | Splice Site (SNP) | VAF 16/136 reads (12%) | hotspot (GDC flag); catalogued as rs730881677, CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.1859G>T p.R620L | Missense Mutation (SNP) | VAF 35/376 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as rs139539832; called by muse, mutect2
- CARD11 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 36/286 reads (13%) | catalogued as COSV100712197, COSV62716688; called by muse, mutect2, varscan2
- CCDC30 | c.1328A>G p.Y443C (on ENST00000340612; = p.Y400C on NM_001080850.3) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as rs765148066; called by muse, mutect2, varscan2
- CD247 | c.436A>T p.S146C (on ENST00000362089 / NM_198053.3; = p.S145C on NM_000734.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/349 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54819458; called by muse, mutect2
- CRYBG3 | c.6231G>C p.R2077S | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1318700116; called by muse, mutect2
- CSMD3 | c.8929T>C p.C2977R (on ENST00000297405 / NM_001363185.1; = p.C2808R on NM_052900.3) | Missense Mutation (SNP) | VAF 22/404 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1397257828, COSV99849543; called by muse, mutect2
- CSMD3 | c.5000T>C p.I1667T (on ENST00000297405 / NM_001363185.1; = p.I1563T on NM_052900.3) | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1248060954; called by mutect2, varscan2
- DCAF12L1 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100948105; called by muse, mutect2
- EFCAB6 | c.2213G>C p.R738T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV53059835; called by muse, mutect2, varscan2
- EIF2S3B | c.244G>C p.G82R | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs949799953; called by muse, mutect2, varscan2
- GPRIN3 | c.233T>C p.M78T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs755141660; called by muse, mutect2, varscan2
- GRIN2B | c.287G>C p.G96A | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101662960; called by muse, mutect2
- KCNJ11 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.958); catalogued as rs1310564746; called by muse, mutect2, varscan2
- KEAP1 | c.481A>G p.M161V | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV50277698; called by muse, mutect2, varscan2
- MAGEB3 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV64397621; called by muse, mutect2, varscan2
- MCHR1 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.05); catalogued as rs754736606; called by muse, mutect2
- MYBL1 | c.2194C>A p.Q732K | Missense Mutation (SNP) | VAF 15/282 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV72919024; called by muse, mutect2
- NAP1L3 | c.1336C>A p.P446T | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV59075162; called by muse, mutect2
- OR13C5 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66165006; called by muse, mutect2
- PGBD5 | c.806A>G p.Y269C (on ENST00000525115; = p.Y338C on NM_001258311.2) | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV58412812; called by muse, mutect2
- PSKH2 | c.777C>A p.F259L | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV52609095; called by muse, mutect2
- RHOU | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV64208346; called by muse, mutect2, varscan2
- SPRY1 | c.112A>G p.I38V | Missense Mutation (SNP) | VAF 25/329 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.048); catalogued as rs769362140; called by muse, mutect2
- TDRD15 | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.413); catalogued as rs1243457651; called by muse, mutect2
- TEX101 | c.210G>C p.G70= (on ENST00000598265 / NM_001130011.3; = p.G88= on NM_031451.4) | Splice Region (SNP) | VAF 5/25 reads (20%) | catalogued as COSV53661390; called by muse, mutect2, varscan2
- TMEM255A | c.372C>A p.Y124* | Nonsense Mutation (SNP) | VAF 15/180 reads (8%) | catalogued as COSV100550391, COSV59031968; called by muse, mutect2
- TRIM25 | c.1727G>T p.R576L | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs760096757, COSV57544346, COSV57545313; called by muse, mutect2, varscan2
- WT1 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV100188171; called by muse, mutect2, varscan2
- ZKSCAN7 | c.252G>T p.M84I | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as COSV56273481; called by muse, mutect2
- ZNF275 | c.647G>T p.R216L | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV64705472; called by muse, mutect2, varscan2
- ABCA1 | c.6619T>G p.S2207A | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ACTL6B | c.427A>T p.I143F | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- AGAP1 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); called by muse, mutect2
- ARHGAP10 | c.1102G>T p.G368C | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2
- ARHGEF18 | c.1748A>T p.Q583L (on ENST00000359920 / NM_001130955.2; = p.Q479L on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2
- ARID1A | c.4548_4570del p.A1517Wfs*7 | Frame Shift Del (DEL) | VAF 14/87 reads (16%) | called by mutect2, pindel
- ATR | c.9A>T p.E3D | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2
- ATRAID | c.124G>C p.G42R | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2
- ATRNL1 | c.2843C>A p.T948N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATRX | c.3329C>T p.S1110F | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- BMP1 | c.2848G>A p.A950T | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.01); called by muse, mutect2
- BTBD1 | c.850_851insC p.E284Afs*16 | Frame Shift Ins (INS) | VAF 10/98 reads (10%) | called by mutect2, pindel
- C17orf80 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.79); called by muse, mutect2
- CFAP45 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 19/126 reads (15%) | called by muse, mutect2, varscan2
- COX7B | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.039); called by muse, mutect2
- CTNNA3 | c.1568T>A p.I523K | Missense Mutation (SNP) | VAF 32/333 reads (10%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.861); called by muse, mutect2
- CWH43 | c.1186+2T>C p.X396_splice | Splice Site (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- CYP39A1 | c.809T>A p.L270Q | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- FBXO41 | c.442C>A p.R148S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- FEM1A | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 19/306 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.356); called by muse, mutect2
- FRMPD1 | c.3037T>G p.F1013V | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); called by muse, mutect2
- FRMPD3 | c.4877C>A p.A1626D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.349); called by muse, mutect2
- GPATCH2 | c.54C>A p.S18R | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); called by muse, mutect2
- IL1RAPL1 | c.1685A>T p.K562M | Missense Mutation (SNP) | VAF 36/334 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- KCND2 | c.713T>C p.M238T | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2
- KCNMB3 | c.4C>T p.Q2* | Nonsense Mutation (SNP) | VAF 15/212 reads (7%) | called by muse, mutect2
- KIR3DL2 | c.560C>G p.P187R | Missense Mutation (SNP) | VAF 24/399 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2
- KRT83 | c.1339G>T p.V447L | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRTAP4-8 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.061); called by muse, mutect2
- LAMA1 | c.4487A>C p.Y1496S | Missense Mutation (SNP) | VAF 43/301 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- MUC4 | c.4060T>A p.S1354T | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- MYCBPAP | c.2286G>C p.Q762H | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); called by muse, mutect2
- MYLK | c.3863A>G p.N1288S | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (0.86); PolyPhen benign (0.011); called by muse, mutect2
- MYO1A | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 50/307 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- NLGN3 | c.1795del p.R599Efs*10 (on ENST00000358741 / NM_181303.2; = p.R579Efs*10 on NM_018977.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/95 reads (9%) | called by mutect2, pindel
- NOTCH3 | c.995G>C p.R332P | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8K1 | c.827T>C p.I276T | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- PAPOLG | c.1972_1975del p.L658Kfs*3 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | called by mutect2, pindel, varscan2
- PGBD2 | c.1360A>T p.K454* | Nonsense Mutation (SNP) | VAF 20/147 reads (14%) | called by muse, mutect2, varscan2
- PRDM1 | c.44_54del p.A15Vfs*2 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | called by mutect2, pindel
- RAG2 | c.985C>A p.L329I | Missense Mutation (SNP) | VAF 66/624 reads (11%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.994); called by muse, mutect2
- REPS1 | c.44C>G p.S15* | Nonsense Mutation (SNP) | VAF 15/163 reads (9%) | called by muse, mutect2
- RFX7 | c.3458C>A p.T1153N (on ENST00000559447 / NM_001368074.1; = p.T1250N on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.779); called by muse, mutect2
- SIRT4 | c.837G>T p.K279N | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2
- SLC7A3 | c.1489C>A p.Q497K | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYNE1 | c.6596G>A p.W2199* (on ENST00000367255 / NM_182961.4; = p.W2206* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- TEX15 | c.953A>T p.K318M (on ENST00000256246; = p.K701M on NM_001350162.2) | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- THADA | c.823A>G p.S275G | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- THOC5 | c.1407del p.S470Afs*7 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel, varscan2
- TTN | c.70456G>A p.E23486K (on ENST00000591111; = p.E16062K on NM_003319.4) | Missense Mutation (SNP) | VAF 35/364 reads (10%) | PolyPhen benign (0.359); called by muse, mutect2
- UBR5 | c.3942G>T p.M1314I | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.38); called by muse, mutect2
- UNC80 | c.6165+1G>T p.X2055_splice | Splice Site (SNP) | VAF 6/103 reads (6%) | called by muse, mutect2
- ZGRF1 | c.3499A>G p.I1167V | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF407 | c.6238G>T p.V2080F | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF441 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF441 | c.1010A>T p.E337V | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF850 | c.1936C>T p.Q646* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- ATR | c.6369C>T p.N2123= | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as COSV99052509; called by muse, mutect2, varscan2
- BTK | c.360A>C p.L120= | Silent (SNP) | VAF 28/386 reads (7%) | catalogued as COSV100437502; called by muse, mutect2
- C9orf78 | c.564T>A p.I188= | Silent (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- CFAP65 | c.5610C>T p.N1870= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- FAM83A | c.345G>T p.P115= | Silent (SNP) | VAF 17/153 reads (11%) | called by muse, mutect2, varscan2
- FRMPD3 | c.4674G>T p.L1558= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- IGF2BP2 | c.1107C>T p.S369= | Silent (SNP) | VAF 19/234 reads (8%) | catalogued as rs757933404, COSV60486770; called by muse, mutect2
- IGKV3-15 | c.327G>A p.Q109= | Silent (SNP) | VAF 42/792 reads (5%) | catalogued as rs1434333679; called by muse, mutect2
- IL1B | c.417A>G p.P139= | Silent (SNP) | VAF 26/276 reads (9%) | called by muse, mutect2
- OR51G1 | c.711C>T p.L237= | Silent (SNP) | VAF 12/120 reads (10%) | called by muse, mutect2, varscan2
- OR8B2 | c.261A>T p.S87= | Silent (SNP) | VAF 8/159 reads (5%) | called by muse, mutect2
- PDZD3 | c.1008C>A p.P336= (on ENST00000531114; = p.P256= on NM_024791.4) | Silent (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- POU3F2 | c.900C>T p.G300= | Silent (SNP) | VAF 21/285 reads (7%) | called by muse, mutect2
- PTPRB | c.3378C>T p.L1126= | Silent (SNP) | VAF 28/419 reads (7%) | called by muse, mutect2
- SAMD4B | c.1506C>T p.L502= | Silent (SNP) | VAF 8/103 reads (8%) | called by muse, mutect2
- SNRNP200 | c.3918C>T p.P1306= | Silent (SNP) | VAF 16/125 reads (13%) | called by muse, mutect2, varscan2
- TCF20 | c.4071G>A p.Q1357= | Silent (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- TMC1 | c.606C>T p.L202= | Silent (SNP) | VAF 24/214 reads (11%) | catalogued as COSV52785352; called by muse, mutect2, varscan2
- TRIM11 | c.588G>A p.L196= | Silent (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2, varscan2
- TRIM51GP | c.978A>G p.E326= | Silent (SNP) | VAF 32/388 reads (8%) | called by muse, mutect2
- TSC22D2 | c.180G>A p.E60= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- TXLNB | c.54A>C p.P18= | Silent (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
- UNC80 | c.1266A>C p.S422= | Silent (SNP) | VAF 12/212 reads (6%) | catalogued as COSV99780219; called by muse, mutect2
- WHAMM | c.1350G>T p.L450= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV54495301; called by muse, mutect2, varscan2
- AC073343.1 | n.227C>G | RNA (SNP) | VAF 21/197 reads (11%) | called by muse, mutect2, varscan2
- AGAP7P | n.1136C>T | RNA (SNP) | VAF 39/353 reads (11%) | catalogued as rs1486485876; called by muse, mutect2, varscan2
- ATRX | c.5566+20G>C | Intron (SNP) | VAF 18/216 reads (8%) | called by muse, mutect2
- CCDC162P | n.2592C>A | RNA (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
- CORO6 | c.634-484T>A | Intron (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- DCHS1 | c.*100A>G | 3'UTR (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- HHLA1 | c.140-1076G>T | Intron (SNP) | VAF 17/236 reads (7%) | called by muse, mutect2
- MAP4K2 | c.367-19G>A | Intron (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- NBPF22P | n.526G>T | RNA (SNP) | VAF 30/363 reads (8%) | called by muse, mutect2
- SEMA4F | c.-18G>T | 5'UTR (SNP) | VAF 5/43 reads (12%) | catalogued as rs1271500664; called by muse, mutect2
- ZNF783 | c.802+3687C>A | Intron (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
